Somatic mutation profile of tumor specimen TCGA-06-0173-01A (aliquot TCGA-06-0173-01A-01D-1491-08) from TCGA case TCGA-06-0173, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.7 years (26,549 days).
Specimen TCGA-06-0173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a67eddc-6bf5-44c7-b38a-b9a34acb0ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0173-10B (Blood Derived Normal), aliquot TCGA-06-0173-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14df9543-c061-4b33-aa2e-280cce4fe511

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, RNA 1, Splice Site 1, Frame Shift Del 1, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD10 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as COSV56325518; called by muse, mutect2, varscan2
- ACTA2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as rs1223323843, CM113525, COSV56517117; called by muse, mutect2
- ANKRD10 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1246366714, COSV57444419; called by muse, mutect2, varscan2
- ANO4 | c.2803C>T p.R935C (on ENST00000392977 / NM_001286615.2; = p.R900C on NM_178826.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs139827573, COSV54585067; called by muse, mutect2, varscan2
- APLP2 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53841903; called by muse, mutect2, varscan2
- BAZ1B | c.1150A>T p.I384F | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.185); catalogued as COSV59992242; called by muse, mutect2, varscan2
- CACNA1A | c.5471G>A p.R1824Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745900417, COSV64202519; called by muse, mutect2, varscan2
- CAPNS1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.761); catalogued as COSV55822423, COSV55823124; called by muse, mutect2, varscan2
- CCDC112 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.691); catalogued as COSV65473482; called by muse, mutect2, varscan2
- CDH9 | c.1127A>T p.D376V | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50322199; called by muse, mutect2, varscan2
- CDX4 | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65171728; called by muse, mutect2, varscan2
- CEACAM20 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs753959553, COSV57602225; called by muse, mutect2, varscan2
- CEP126 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as rs145886481, COSV54827270; called by muse, mutect2, varscan2
- CNTNAP2 | c.3095G>T p.R1032I | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV62145712, COSV62209746; called by muse, mutect2
- CPXCR1 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52163210; called by muse, mutect2, varscan2
- CRYBG1 | c.2851T>C p.S951P | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64812956; called by muse, mutect2, varscan2
- DNAH2 | c.4327A>T p.I1443F | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV66721848, COSV66727571; called by muse, mutect2
- DNAH8 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs779369031, COSV59459782; called by muse, mutect2, varscan2
- DNAH9 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); catalogued as COSV52358398; called by muse, mutect2, varscan2
- DSC3 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV64573783; called by muse, mutect2, varscan2
- EPPK1 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs781912098, COSV73261717; called by muse, mutect2, varscan2
- FLT1 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56732655; called by muse, mutect2, varscan2
- GALP | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as rs745797059, COSV62000539; called by muse, mutect2, varscan2
- GUCA1C | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53754143; called by muse, mutect2, varscan2
- HECW1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 126/399 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs374489291; called by muse, mutect2, varscan2
- IMPDH1 | c.794C>T p.A265V (on ENST00000470772 / NM_001142573.2; = p.A351V on NM_000883.4) | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs748397513, COSV58316848; called by muse, mutect2, varscan2
- LILRB1 | c.1733A>G p.Q578R (on ENST00000427581; = p.Q528R on NM_006669.6) | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV61119381; called by muse, mutect2, varscan2
- LILRB5 | c.1499C>A p.A500D (on ENST00000449561 / NM_001081442.3; = p.A499D on NM_006840.5) | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV60254253, COSV60259176; called by muse, mutect2
- LRAT | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs748491424, COSV60477075; called by muse, mutect2, varscan2
- MUC16 | c.18245G>A p.S6082N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV67475857; called by muse, mutect2, varscan2
- NBEAL1 | c.4508T>C p.I1503T | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV71374792; called by muse, mutect2
- NETO1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs778182466, COSV55001979; called by muse, mutect2, varscan2
- NFASC | c.1507G>A p.A503T (on ENST00000339876 / NM_001378329.1; = p.A514T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs780692017, COSV58359304; called by muse, mutect2, varscan2
- NRG1 | c.43G>C p.V15L (on ENST00000523534; = p.V162L on NM_013962.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV73062044; called by muse, mutect2
- OBSCN | c.15826C>T p.R5276C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs564170262, COSV52791013; called by muse, mutect2
- OR2F2 | c.644T>A p.L215Q | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68832982; called by muse, mutect2, varscan2
- OR51E2 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV67807863, COSV67808620; called by muse, mutect2, varscan2
- OR5I1 | c.344T>A p.F115Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV56887753; called by muse, mutect2, varscan2
- PARD6B | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763915421, COSV100859931, COSV65404197; called by muse, mutect2, varscan2
- PIK3CG | c.2807G>C p.C936S | Missense Mutation (SNP) | VAF 92/425 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV63250026; called by muse, mutect2, varscan2
- PPFIA2 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1279396958, COSV61039892; called by muse, mutect2, varscan2
- RIMS2 | c.2882G>A p.R961Q (on ENST00000666250 / NM_001348490.2; = p.R769Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); catalogued as rs368813886; called by muse, mutect2, varscan2
- ROCK1 | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67696899; called by muse, mutect2
- RTEL1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1206278611, COSV58896760; called by muse, mutect2, varscan2
- SLC22A2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs1229793943, COSV65266760; called by muse, mutect2, varscan2
- SLC22A9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as rs760458545, COSV54165823; called by muse, mutect2, varscan2
- SULF1 | c.1088A>T p.D363V | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52685742; called by muse, mutect2, varscan2
- TBC1D32 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV51546765; called by muse, mutect2, varscan2
- TENM2 | c.6919C>T p.R2307W (on ENST00000518659 / NM_001122679.2; = p.R2068W on NM_001080428.3) | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69124242; called by muse, mutect2, varscan2
- TGM5 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370983556, CM1411737; called by muse, mutect2, varscan2
- TMEM132D | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV70611348; called by muse, mutect2, varscan2
- TRIML1 | c.1170G>T p.W390C | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs777991114, COSV60195216; called by muse, mutect2, varscan2
- UBE3C | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); catalogued as COSV61954323; called by muse, mutect2, varscan2
- VWA3A | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs746722541, COSV55392443; called by muse, mutect2, varscan2
- ZGRF1 | c.3039_3040del p.D1015* | Frame Shift Del (DEL) | VAF 53/181 reads (29%) | catalogued as COSV58410562; called by mutect2, pindel, varscan2
- ZNF597 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV57084820; called by muse, mutect2, varscan2
- ARPC4 | c.122+2_122+5del p.X41_splice | Splice Site (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel
- ADGRF3 | c.2940C>A p.P980= (on ENST00000311519 / NM_001145168.1; = p.P781= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV61051351; called by muse, mutect2, varscan2
- AMY1B | c.963C>T p.G321= | Silent (SNP) | VAF 112/1096 reads (10%) | catalogued as rs563962104, COSV100375538; called by muse, varscan2
- BIVM-ERCC5 | c.1242C>T p.I414= | Silent (SNP) | VAF 84/207 reads (41%) | catalogued as COSV57280710; called by muse, mutect2, varscan2
- CALR | c.609G>T p.L203= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as COSV57129601; called by muse, mutect2, varscan2
- FNDC1 | c.1872G>A p.A624= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs200852800, COSV51934736; called by muse, mutect2, varscan2
- FOXN1 | c.936C>T p.P312= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as rs767538384, COSV56882662; called by muse, mutect2, varscan2
- GATA1 | c.1017G>A p.G339= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV64962640; called by muse, mutect2
- GRM4 | c.273C>T p.N91= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs759833290, COSV65213812; called by muse, mutect2, varscan2
- ISG20L2 | c.45C>G p.P15= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV57460650; called by muse, mutect2
- LENG8 | c.1420C>A p.R474= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV58728810; called by mutect2, varscan2
- MYBBP1A | c.933G>A p.A311= | Silent (SNP) | VAF 92/174 reads (53%) | catalogued as rs149464957; called by muse, mutect2, varscan2
- MYOM1 | c.4785C>T p.N1595= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs777424606, COSV55294951; called by muse, mutect2, varscan2
- NDUFB11 | c.381A>G p.K127= (on ENST00000377811 / NM_001135998.3; = p.K137= on NM_019056.6) | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV52102483; called by muse, mutect2
- OR10C1 | c.447G>A p.A149= (on ENST00000622521; = p.A147= on NM_013941.3) | Silent (SNP) | VAF 72/173 reads (42%) | catalogued as COSV65823379; called by muse, mutect2, varscan2
- PML | c.819C>T p.A273= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs112627818, COSV51442071, COSV51449092; called by muse, mutect2, varscan2
- SLFN13 | c.2106G>A p.L702= | Silent (SNP) | VAF 183/285 reads (64%) | catalogued as COSV53194270; called by muse, mutect2, varscan2
- TMCO4 | c.96G>A p.R32= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV53874475; called by muse, mutect2, varscan2
- UBASH3B | c.639G>A p.V213= | Silent (SNP) | VAF 171/412 reads (42%) | catalogued as COSV52497368; called by muse, mutect2, varscan2
- YIPF6 | c.552G>T p.R184= | Silent (SNP) | VAF 75/202 reads (37%) | catalogued as COSV65855966; called by muse, mutect2, varscan2
- DOCK8 | c.-61G>A | 5'UTR (SNP) | VAF 18/29 reads (62%) | catalogued as rs760849727, COSV66688286; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85831A>T | Intron (SNP) | VAF 104/262 reads (40%) | catalogued as COSV72279542; called by muse, mutect2, varscan2
- OR2W5 | n.645C>T | RNA (SNP) | VAF 55/151 reads (36%) | catalogued as rs753312079; called by muse, mutect2, varscan2
